Somatic mutation profile of tumor specimen TCGA-DX-A1KU-01A (aliquot TCGA-DX-A1KU-01A-32D-A24N-09) from TCGA case TCGA-DX-A1KU, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 82.3 years (30,054 days).
Specimen TCGA-DX-A1KU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1b11422-bb96-4fad-8d91-adc147f208c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A1KU-10A (Blood Derived Normal), aliquot TCGA-DX-A1KU-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4d77585-ab50-4beb-aa9f-7c3d1ef39c5e

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 10, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMHR2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs767061692, COSV99143071; called by muse, mutect2, varscan2
- ATP1A3 | c.2966G>A p.S989N (on ENST00000545399 / NM_001256214.2; = p.S976N on NM_152296.5) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs781891861; called by muse, mutect2
- CD207 | c.573T>G p.I191M | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs781829207; called by muse, mutect2
- CHD7 | c.3720C>G p.N1240K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV101418262; called by muse, mutect2, varscan2
- FCGR2C | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100912845; called by muse, mutect2
- FLRT3 | c.1297A>G p.M433V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs201525960; called by muse, mutect2, varscan2
- HYDIN | c.14029A>T p.T4677S | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.194); catalogued as COSV101125098; called by muse, mutect2, varscan2
- MUC16 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV67460973; called by muse, mutect2, varscan2
- MYO5B | c.2995C>A p.R999S | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs755870645, COSV53211850; called by muse, mutect2, varscan2
- NLRP5 | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs565850613, COSV101173707; called by muse, mutect2, varscan2
- RD3 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs140156866, COSV65362156; called by muse, mutect2, varscan2
- WDR7 | c.2123C>G p.S708C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV54365536; called by muse, mutect2
- ZNF267 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV56250349; called by mutect2, varscan2
- ZNF311 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777896975, COSV65853011; called by muse, mutect2, varscan2
- ZSCAN10 | c.2149C>T p.R717C (on ENST00000252463; = p.R772C on NM_032805.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768699536; called by muse, mutect2, varscan2
- ABCB11 | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- ABCC10 | c.1876G>T p.G626C (on ENST00000372530 / NM_001198934.2; = p.G598C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AK8 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BSDC1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHAF1A | c.2738A>C p.D913A | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2
- DQX1 | c.973T>G p.W325G | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- KLK13 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MAP3K19 | c.251T>C p.V84A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- MGAM | c.1423A>G p.K475E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MYH4 | c.5626C>A p.Q1876K | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NCKAP5 | c.5660G>A p.G1887D | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2
- NPAS3 | c.416G>T p.S139I (on ENST00000356141 / NM_001164749.2; = p.S107I on NM_022123.3) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PCDHA12 | c.1421T>C p.I474T | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCLO | c.13994C>A p.P4665H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PHLDB1 | c.2587G>T p.V863L | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.242); called by muse, mutect2
- PLB1 | c.2005T>A p.W669R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PTPRU | c.917T>A p.L306H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RAMP2 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- SH3PXD2B | c.384C>A p.D128E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLITRK3 | c.533T>A p.L178Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPHKAP | c.1731del p.E578Rfs*2 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- TRDN | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.62); called by muse, mutect2
- TTC39A | c.83G>C p.C28S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- TTN | c.51410G>C p.R17137T (on ENST00000591111; = p.R9713T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- UPF2 | c.575A>T p.D192V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FLRT3 | c.357C>T p.I119= | Silent (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- GUCY2C | c.1074C>T p.L358= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as rs775938690; called by muse, mutect2, varscan2
- LAIR2 | c.114G>T p.V38= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs762339729; called by muse, mutect2
- MYO18B | c.2100C>T p.L700= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs1365356357; called by muse, mutect2, varscan2
- NETO1 | c.828A>T p.R276= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- OR51G1 | c.808C>T p.L270= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV58971136; called by muse, mutect2, varscan2
- PDIA2 | c.1089C>T p.F363= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV51991813; called by muse, mutect2, varscan2
- SMARCC2 | c.2403G>A p.G801= | Silent (SNP) | VAF 110/182 reads (60%) | called by muse, mutect2, varscan2
- UBXN11 | c.1338C>A p.P446= (on ENST00000374221 / NM_183008.2; = p.P413= on NM_145345.2) | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as COSV53330436; called by muse, mutect2
- ZNF267 | c.2035C>A p.R679= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV56254916; called by mutect2, varscan2
- CREM | c.891-318C>T | Intron (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- MGAM | c.4618+5573T>A | Intron (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
